Gene-level copy-number profile of tumor specimen HTMCP-02-06-01037-01A from CGCI case HTMCP-02-06-01037, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung.
Specimen HTMCP-02-06-01037-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3e836e27-f354-4923-a7cb-392b8ce2e17a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-06-01037-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/ffe391f0-d604-4ecb-94cd-93a61a8913c3

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 369; copy number 1: 29; copy number 2: 1,236; copy number 3: 6,371; copy number 4: 12,450; copy number 5: 13,782; copy number 6: 11,303; copy number 7: 6,928; copy number 8: 2,697; copy number 9: 580; copy number 10: 451; copy number 11: 1,314; copy number 12: 383; copy number 13: 811; copy number 14: 23; copy number 15: 41; copy number 16: 7; copy number 17: 85; copy number 18: 40; copy number 30: 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr5:145,337,932–145,381,670, 1 gene: AC137770.1.
- chr7:6,080,704–6,093,085, 1 gene: AC004895.1.
- chr9:41,890,314–42,569,353, 16 genes (within-gene range 0–2): CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1.
- chr14:105,583,731–105,673,314, 9 genes (within-gene range 0–4): IGHA2, IGHE, IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.
- chr14:106,257,762–106,324,760, 14 genes (within-gene range 0–4): IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26, IGHVIII-26-1, IGHVII-26-2, IGHV7-27, IGHV4-28.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 2,705 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:4,866,521–4,874,759, 1 gene, copy number 11: AC026415.1.
- chr5:6,686,325–45,895,970, 554 genes, copy number 11–12 (broad region; genes not listed).
- chr8:46,028,804–144,336,482, 1,442 genes, copy number 11–18 (broad region; genes not listed).
- chr15:24,162,754–24,169,948, 1 gene, copy number 30: PWRN2.
- chr20:22,343,693–23,638,473, 42 genes, copy number 11: AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2.
- chr20:24,063,255–24,226,013, 1 gene, copy number 11 (within-gene range 10–11): LINC01721.
- chr20:24,237,255–26,251,546, 55 genes, copy number 11: RNU1-23P, AL158090.1, GAPDHP53, SYNDIG1, AL157413.1, AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr20:31,257,664–55,075,140, 605 genes, copy number 11–12 (broad region; genes not listed).
- chr20:59,460,619–59,847,711, 4 genes, copy number 11: PIEZO1P1, AL389889.1, PHACTR3, PHACTR3-AS1.

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
